Somatic mutation profile of tumor specimen MBCProject_0203_T2_WES (aliquot MBCProject_0203_T2_WES_1) from CMI case MBCProject_0203, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 48.4 years (17,691 days).
Specimen MBCProject_0203_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 220c794d-3066-46c0-955a-75cbdb7b6062.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0203_SALIVA (Saliva), aliquot MBCProject_0203_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e1d13ae-1bff-4b95-b313-b64de0330b3d

The open-access MAF lists 51 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 8, Nonsense Mutation 2, In Frame Del 1, Intron 1, Splice Site 1, 5'UTR 1, 3'Flank 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASTN1 | c.3807C>G p.S1269R | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as COSV100706916; called by muse, mutect2, varscan2
- CBY2 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 19/408 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV60118086; called by muse, mutect2
- DOC2A | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58751371; called by muse, mutect2
- FAM20C | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.018); catalogued as rs1245703345; called by muse, mutect2
- HUWE1 | c.3979G>T p.D1327Y | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53339081; called by muse, mutect2
- NR6A1 | c.563A>T p.N188I (on ENST00000487099 / NM_033334.4; = p.N184I on NM_001489.5) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as COSV60633434; called by muse, mutect2, varscan2
- POU6F2 | c.1130C>A p.T377K | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs1472321299; called by muse, mutect2
- PRKCD | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs143488209; ClinVar: uncertain significance; called by muse, mutect2
- TGM2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as rs577909675; called by muse, mutect2, varscan2
- ANO4 | c.2589C>A p.D863E (on ENST00000392977 / NM_001286615.2; = p.D828E on NM_178826.4) | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP42 | c.755G>T p.R252M | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- ARHGEF11 | c.2779A>T p.T927S | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2
- ATP2B4 | c.148_162delinsCTA p.G50_N53del | In Frame Del (DEL) | VAF 15/148 reads (10%) | called by pindel, varscan2*
- CCSER1 | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DDX31 | c.2372A>G p.Y791C | Missense Mutation (SNP) | VAF 15/333 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- DNAJC3 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- EMC1 | c.1038C>G p.S346R | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- GCM2 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- GRK2 | c.808A>C p.I270L | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- HSF5 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- IQCF1 | c.171+1_171+6del p.X57_splice | Splice Site (DEL) | VAF 12/134 reads (9%) | called by mutect2, pindel
- KIAA1109 | c.8012A>G p.K2671R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KIAA1549L | c.3911C>T p.P1304L (on ENST00000321505; = p.P1601L on NM_012194.3) | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIF1A | c.4459A>T p.S1487C (on ENST00000320389 / NM_001379639.1; = p.S1479C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); called by muse, mutect2
- MAOA | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- MRPL11 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2
- MRPL17 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 28/361 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- MUC16 | c.34895C>A p.T11632N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYH7 | c.1074C>A p.H358Q | Missense Mutation (SNP) | VAF 21/263 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2
- OXCT1 | c.484G>T p.G162W | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSG4 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- RABGAP1L | c.931A>T p.K311* | Nonsense Mutation (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- RPGR | c.2857A>G p.I953V (on ENST00000339363 / NM_001367249.1; = p.I748V on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, varscan2
- SERPINA6 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- SLC35A1 | c.988T>G p.S330A | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SPRYD3 | c.731A>C p.D244A | Missense Mutation (SNP) | VAF 16/353 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- TAF1L | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2
- ZSCAN22 | c.206A>T p.H69L | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- CACNA1B | c.1695C>A p.A565= | Silent (SNP) | VAF 24/243 reads (10%) | called by muse, mutect2, varscan2
- COL20A1 | c.1293G>A p.T431= | Silent (SNP) | VAF 39/268 reads (15%) | catalogued as rs780583500, COSV58918554; called by muse, mutect2, varscan2
- GAL3ST3 | c.924C>T p.H308= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs1222376422; called by muse, mutect2
- ITGA9 | c.519C>T p.G173= | Silent (SNP) | VAF 29/427 reads (7%) | called by muse, mutect2
- KCND3 | c.1749G>A p.Q583= | Silent (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- MAP4K4 | c.516T>C p.F172= | Silent (SNP) | VAF 50/514 reads (10%) | catalogued as rs1268907751; called by muse, mutect2
- MUC1 | c.3705C>G p.P1235= (on ENST00000611571 / NM_001371720.1; = p.P246= on NM_002456.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- TRAV6 | c.309C>G p.V103= | Silent (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- AC090151.1 | chr8:54701643 A>T | 3'Flank (SNP) | VAF 24/118 reads (20%) | called by muse, mutect2, varscan2
- CRIM1 | c.2429-5437C>T | Intron (SNP) | VAF 24/180 reads (13%) | called by muse, varscan2
- GPATCH8 | c.*1799A>G | 3'UTR (SNP) | VAF 26/502 reads (5%) | called by muse, mutect2
- POLR2H | c.-53C>G | 5'UTR (SNP) | VAF 63/425 reads (15%) | called by muse, mutect2, varscan2
- TK1 | chr17:78187097 A>G | 5'Flank (SNP) | VAF 12/162 reads (7%) | catalogued as rs1216718360; called by muse, mutect2
